Somatic mutation profile of tumor specimen MP2PRT-PAVUNT-TMP1-A (aliquot MP2PRT-PAVUNT-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVUNT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,127 days).
Specimen MP2PRT-PAVUNT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81e0b59a-5e08-4da4-98b9-7e622d22c164.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUNT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUNT-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eec308a-df26-42fd-9fab-c8fd2dd45284

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 58/275 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DLGAP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 157/409 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1412135893, COSV52396015; called by muse, mutect2, varscan2
- DOCK3 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774398189, COSV56509467; called by muse, mutect2
- TMEM26 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 139/552 reads (25%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs1017279780, COSV53262420; called by muse, mutect2, varscan2
- VIL1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs779057580, COSV99945893; called by muse, mutect2, varscan2
- NRXN1 | c.1233T>A p.D411E | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- UBXN4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WIPF3 | c.876G>A p.P292= | Silent (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- ZNF521 | c.2478A>G p.K826= | Silent (SNP) | VAF 51/454 reads (11%) | called by muse, mutect2, varscan2
